Somatic mutation profile of tumor specimen TCGA-EB-A57M-01A (aliquot TCGA-EB-A57M-01A-51D-A30X-08) from TCGA case TCGA-EB-A57M, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 56.7 years (20,698 days).
Specimen TCGA-EB-A57M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6834b8ce-342e-40ad-8ca6-b35372ff274b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A57M-10A (Blood Derived Normal), aliquot TCGA-EB-A57M-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93e17fa9-c010-40bb-bda4-0e71323a1468

The open-access MAF lists 43 somatic variants for this specimen: 38 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 3, 3'UTR 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 130/275 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASAP2 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55637617; called by muse, mutect2
- ATM | c.6975+1G>C p.X2325_splice | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV53767841, COSV53770047; called by muse, mutect2, varscan2
- ATP1B3 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53951434; called by muse, mutect2, varscan2
- CCDC90B | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52624928; called by muse, varscan2
- CDK14 | c.470A>G p.N157S (on ENST00000380050 / NM_001287135.2; = p.N139S on NM_012395.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV56049621; called by muse, mutect2
- CLEC3B | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56109850, COSV56110404; called by muse, mutect2, varscan2
- CNGA1 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as COSV62056585; called by muse, mutect2
- CPA1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50574407; called by muse, mutect2
- DDR1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs149823598; called by muse, mutect2
- DNHD1 | c.13493C>T p.T4498M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV54442634; called by muse, mutect2, varscan2
- EHD3 | c.1562T>G p.L521R | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59032695; called by muse, mutect2, varscan2
- EPB41L1 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs748237712, COSV52443577; called by muse, mutect2, varscan2
- FAT2 | c.10945C>T p.R3649W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142359154; called by muse, mutect2, varscan2
- FREM2 | c.4012T>G p.S1338A | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs770510437, COSV54849872, COSV54853769; called by muse, mutect2, varscan2
- FSIP2 | c.17971G>A p.A5991T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as rs769297860, COSV58097686; called by muse, mutect2, varscan2
- GOLGB1 | c.4906G>T p.V1636L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.163); catalogued as COSV61470213; called by muse, mutect2, varscan2
- GYS1 | c.119-1G>A p.X40_splice | Splice Site (SNP) | VAF 12/226 reads (5%) | catalogued as COSV54405087; called by muse, mutect2
- KCNH4 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52920698; called by muse, mutect2
- LNX2 | c.1759A>G p.M587V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60337959; called by muse, mutect2, varscan2
- MACC1 | c.2429T>C p.L810P | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60545942; called by muse, mutect2
- MARCHF8 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV60574509; called by muse, mutect2
- NLRC4 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.679); catalogued as rs774834511, COSV61591279; called by muse, mutect2, varscan2
- NOS1AP | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV62639547; called by muse, mutect2, varscan2
- NOTCH1 | c.6088T>C p.S2030P | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53087559; called by muse, mutect2, varscan2
- NSD3 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57673241; called by muse, mutect2, varscan2
- OR7G3 | c.686C>A p.P229Q | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs1404208779, COSV59640942, COSV59641283; called by muse, mutect2
- PRDM9 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV57012182, COSV57015325, COSV99689899; called by muse, mutect2, varscan2
- PSD4 | c.1570G>C p.A524P | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV55529714; called by muse, mutect2, varscan2
- RP1L1 | c.5795A>T p.E1932V | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV66759463; called by muse, mutect2
- SEC24B | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54505540; called by muse, mutect2, varscan2
- SLC1A3 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54319773; called by muse, mutect2, varscan2
- SYNE1 | c.19199G>A p.R6400H (on ENST00000367255 / NM_182961.4; = p.R6329H on NM_033071.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs746141355, COSV55081766; ClinVar: uncertain significance; called by mutect2, varscan2
- TENM4 | c.7524G>A p.M2508I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53663724; called by muse, mutect2
- TENM4 | c.7222G>T p.D2408Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV53608601, COSV53656348; called by muse, mutect2, varscan2
- TENM4 | c.7102G>A p.A2368T | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53663754; called by muse, mutect2, varscan2
- TIMD4 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50859360; called by muse, mutect2
- ZNF207 | c.805_808del p.S269Qfs*38 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- BIRC5 | c.243G>C p.S81= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV56957351; called by muse, mutect2, varscan2
- POLK | c.603C>T p.Y201= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs914377719, COSV54039023; called by muse, mutect2, varscan2
- TIGD7 | c.858C>T p.D286= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs148242088; called by muse, mutect2, varscan2
- CPLANE1 | c.*5251del | 3'UTR (DEL) | VAF 15/107 reads (14%) | called by pindel, varscan2
- CPLANE1 | c.*5194G>A | 3'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as COSV57058719; called by muse, varscan2
